Somatic mutation profile of tumor specimen TARGET-30-PALWVJ-01A (aliquot TARGET-30-PALWVJ-01A-01W) from TARGET case TARGET-30-PALWVJ, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Medulla of adrenal gland; Age at diagnosis: 4.2 years (1,544 days).
Specimen TARGET-30-PALWVJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6517cd93-98c5-4e19-b1a2-d30df6babaff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PALWVJ-10A (Blood Derived Normal), aliquot TARGET-30-PALWVJ-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97aec030-dd66-484a-a84b-ab57a001f7ad

The open-access MAF lists 36 somatic variants for this specimen: 27 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 5, RNA 4, Nonsense Mutation 2, Translation Start Site 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP25 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 89/458 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.743); catalogued as COSV54900910; called by muse, mutect2, varscan2
- ARHGEF40 | c.1570C>A p.P524T | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV53879353; called by muse, mutect2, varscan2
- ATP10B | c.3735G>A p.M1245I | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59147891; called by muse, mutect2, varscan2
- ATP5MF | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs113813644, COSV52854139; called by muse, mutect2, varscan2
- CDKN1A | c.184G>T p.D62Y | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV55188055, COSV55192281; called by muse, mutect2, varscan2
- DNAH11 | c.9742G>T p.V3248F | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV60949887, COSV60972319; called by muse, mutect2, varscan2
- EVA1A | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.187); catalogued as rs1051330994, COSV52057694; called by muse, mutect2, varscan2
- FANCI | c.232T>A p.S78T | Missense Mutation (SNP) | VAF 115/269 reads (43%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.97); catalogued as COSV55524136; called by muse, mutect2, varscan2
- FGD4 | c.793A>G p.S265G | Missense Mutation (SNP) | VAF 55/284 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.154); catalogued as COSV56782414; called by muse, mutect2, varscan2
- HMCN1 | c.3992A>G p.Y1331C | Missense Mutation (SNP) | VAF 68/350 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.855); catalogued as rs376178458; called by muse, mutect2, varscan2
- IFT88 | c.1205C>A p.S402Y (on ENST00000319980 / NM_001318493.2; = p.S393Y on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 122/255 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV60672425; called by muse, mutect2, varscan2
- LRP1B | c.4231G>T p.G1411C | Missense Mutation (SNP) | VAF 74/224 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67193185; called by muse, mutect2, varscan2
- MIOS | c.1987G>T p.E663* | Nonsense Mutation (SNP) | VAF 177/923 reads (19%) | catalogued as COSV100403005, COSV60767897; called by muse, mutect2, varscan2
- OR4C11 | c.752C>A p.P251Q | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56352721; called by muse, mutect2
- OTOP3 | c.674G>C p.W225S | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100172642, COSV60912821; called by muse, mutect2, varscan2
- PIGN | c.523G>C p.D175H | Missense Mutation (SNP) | VAF 161/431 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62948591; called by muse, mutect2, varscan2
- RBMX2 | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 82/101 reads (81%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as COSV59728642; called by muse, mutect2, varscan2
- RCOR3 | c.738C>A p.D246E | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV65365387; called by muse, mutect2, varscan2
- SLC18B1 | c.352G>T p.G118C | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51593946, COSV99259242; called by muse, mutect2, varscan2
- TLE4 | c.1032G>T p.R344S | Missense Mutation (SNP) | VAF 20/414 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV99511512; called by muse, mutect2
- TLL2 | c.289G>T p.G97W | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV63571670; called by muse, mutect2, varscan2
- XKR3 | c.689T>A p.L230Q | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV58885376; called by muse, varscan2
- ALAS2 | c.401A>T p.Q134L | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ALAS2 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 25/72 reads (35%) | called by muse, mutect2, varscan2
- LILRA6 | c.636C>G p.D212E | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RALGAPA2 | c.3903T>A p.V1301= | Splice Region (SNP) | VAF 32/378 reads (8%) | called by muse, mutect2
- TSPYL4 | c.709_743del p.R237Efs*25 | Frame Shift Del (DEL) | VAF 16/79 reads (20%) | called by mutect2, pindel
- BCLAF1 | c.144T>C p.S48= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV62141352; called by muse, mutect2, varscan2
- MEF2C | c.180C>G p.T60= | Silent (SNP) | VAF 110/292 reads (38%) | catalogued as COSV60928509; called by muse, mutect2, varscan2
- OR51I2 | c.462C>A p.I154= | Silent (SNP) | VAF 44/337 reads (13%) | catalogued as rs1312750353, COSV58298374; called by muse, mutect2, varscan2
- PXDNL | c.3861C>A p.I1287= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as rs1346990494, COSV62484568; called by muse, mutect2, varscan2
- RAB3GAP2 | c.3840C>T p.N1280= | Silent (SNP) | VAF 29/296 reads (10%) | called by muse, mutect2
- AC244258.1 | n.612G>T | RNA (SNP) | VAF 16/132 reads (12%) | called by muse, mutect2, varscan2
- ARPP19P2 | n.159G>T | RNA (SNP) | VAF 12/306 reads (4%) | called by muse, mutect2
- OFCC1 | n.425G>A | RNA (SNP) | VAF 59/316 reads (19%) | called by muse, mutect2, varscan2
- TUBB7P | n.1007A>G | RNA (SNP) | VAF 6/32 reads (19%) | called by mutect2, varscan2
